Somatic mutation profile of tumor specimen TCGA-4K-AA1H-01A (aliquot TCGA-4K-AA1H-01A-11D-A435-10) from TCGA case TCGA-4K-AA1H, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 26.4 years (9,658 days).
Specimen TCGA-4K-AA1H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca79bbea-7044-44be-8bb8-7a85ba6b86ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4K-AA1H-10A (Blood Derived Normal), aliquot TCGA-4K-AA1H-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/603bc053-68c5-422e-ac2f-c4adc77fdccf

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Splice Region 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ZMYM3 | c.143del p.P48Lfs*65 | Frame Shift Del (DEL) | VAF 12/139 reads (9%) | catalogued as rs757506048; called by mutect2, pindel
- EML6 | c.3498G>A p.E1166= | Splice Region (SNP) | VAF 19/312 reads (6%) | called by muse, mutect2
- EPHX1 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- WDR74 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SLTM | c.618A>G p.Q206= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
